Surgical pathology report (de-identified scan), TCGA case TCGA-86-8281, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8281-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
	Labeled right lower lobe. Received fresh for intraoperative consultation is a 7.0 x 3.2 x 2.3 cm stapled wedge of lung. The pleural surface is gray-tan and smooth with a previous incision that reveals a 2.6 x 1.8 x 1.5 cm tan subpleural mass. A portion is sampled for frozen section. The remaining cut surfaces are tan to red and spongy with no other lesions noted.	Sections show lung in which there is a discrete tumor mass consisting of closely packed malignant neoplastic glandular structures, some of which have a papillary configuration with overall features of invasive moderately differentiated adenocarcinoma. No squamous component is identified.	LUNG CARCINOMA CHECKLIST 1. Tumor Type: Adenocarcinoma. 2. Tumor grade: Moderately differentiated. 3. Tumor location: Right lower lobe. 4. Tumor size: 2.6 cm. 5. Angiolymphatic invasion: No. 6. Bronchial margin: Free of tumor. 7. Pleural involvement: Subpleural. 8. Lymph nodes: 0 positive out of 9 found, including subpleural lymph nodes. 9. Size of largest metastatic deposit: Not applicable. 10. TNM: T1 N0 MX.		LUNG TISSUE CHECKLIST Specimen type: Wedge resection, lobectomy Tumor site: Lung Tumor size: 2.6 x 1.8 x 1.5 cm Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/9 positive for metastasis (Subcarinal lymph node, right hilar lymph node, sub 0/9) Lymphatic invasion: Absent Venous invasion: Absent Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
OpenClinica ID	Excision date	Laterality
		Left-lower

Source: NCI Genomic Data Commons file 834b1fe8-ea90-45cc-8343-45f591b81779 (TCGA-86-8281.775DEBD9-A338-412E-86DA-5C132DF883C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).